MMRF case MMRF_1219 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9e3ee1c3-3376-489e-97f6-c5d13ab3a2de

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.1 years (25,601 days); ISS stage: III; Days to last known disease status: 1,629 days (4.5 years); Days to last follow up: 1,629 days (4.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 95 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 127 days; Days to treatment end: 127 days.
   Treatment given: Therapeutic agents: Carfilzomib + Doxorubicin; Regimen or line of therapy: Second line of therapy; Days to treatment start: 278 days; Days to treatment end: 1,307 days (3.6 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,377 days (3.8 years).
   Treatment given: Therapeutic agents: Elotuzumab + Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,377 days (3.8 years); Days to treatment end: 1,433 days (3.9 years).
   Treatment given: Therapeutic agents: Elotuzumab; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,433 days (3.9 years); Days to treatment end: 1,545 days (4.2 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,433 days (3.9 years).
   Treatment given: Therapeutic agents: Elotuzumab; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,545 days (4.2 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1: M Protein 7.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 410 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.53 mg/dL; Immunoglobulin G 83.4 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 15.5 µg/mL; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.23 mmol/L; Albumin 30 g/L; Total Protein 14.4 g/dL; Glucose 5.28 mmol/L.
- Day 68: M Protein 3.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 37.1 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 4 µg/mL; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 9.2 g/dL; Glucose 7.32 mmol/L.
- Day 159: M Protein 3.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 38.1 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.234 g/L; Beta 2 Microglobulin 3.1 µg/mL; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 9.4 g/dL; Glucose 5.17 mmol/L.
- Day 278 (ECOG 0): M Protein 3.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.15 mg/dL; Immunoglobulin G 48.3 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 5.3 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 38 g/L; Total Protein 9.7 g/dL; Glucose 5.61 mmol/L.
- Day 362 (ECOG 1): M Protein 2.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.001 mg/dL; Immunoglobulin G 27.6 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.259 g/L; Beta 2 Microglobulin 3.6 µg/mL; Lactate Dehydrogenase 4 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.45 mmol/L; Albumin 40 g/L; Total Protein 8.3 g/dL; Glucose 4.07 mmol/L.
- Day 446 (ECOG 1): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.01 mg/dL; Immunoglobulin G 20.6 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3.3 µg/mL; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 7.9 g/dL; Glucose 4.95 mmol/L.
- Day 530 (ECOG 1): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 21.2 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 8 g/dL; Glucose 5.23 mmol/L.
- Day 642 (ECOG 1): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.01 mg/dL; Immunoglobulin G 24 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3.5 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.48 mmol/L; Albumin 41 g/L; Total Protein 8.2 g/dL; Glucose 5.17 mmol/L.
- Day 754 (ECOG 0): M Protein 1.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0 mg/dL; Immunoglobulin G 20.5 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.45 mmol/L; Albumin 40 g/L; Total Protein 7.6 g/dL; Glucose 5.17 mmol/L.
- Day 810 (ECOG 0): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0 mg/dL; Immunoglobulin G 20 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.55 mmol/L; Albumin 44 g/L; Total Protein 8 g/dL; Glucose 5.5 mmol/L.
- Day 893 (ECOG 0): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.5 mg/dL; Immunoglobulin G 17.8 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 7.6 g/dL; Glucose 5.23 mmol/L.
- Day 992 (ECOG 1): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0 mg/dL; Immunoglobulin G 16.9 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 4.68 mmol/L.
- Day 1,111 (ECOG 1): M Protein 1.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0 mg/dL; Immunoglobulin G 22.7 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 4.2 µg/mL; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 8.1 g/dL; Glucose 5.67 mmol/L.
- Day 1,195 (ECOG 1): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.2 mg/dL; Immunoglobulin G 5.76 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3.9 µg/mL; Lactate Dehydrogenase 3.92 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 7.4 g/dL; Glucose 5.23 mmol/L.
- Day 1,251 (ECOG 1): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0 mg/dL; Immunoglobulin G 19.8 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3.9 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 7.6 g/dL; Glucose 5.12 mmol/L.
- Day 1,342 (ECOG 1): M Protein 2.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 26.8 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.8 µg/mL; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.6 mmol/L; Albumin 44 g/L; Total Protein 8.6 g/dL; Glucose 5.12 mmol/L.
- Day 1,433 (ECOG 1): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.9 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 7.5 g/dL; Glucose 5.61 mmol/L.
- Day 1,545 (ECOG 1): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.5 mg/dL; Immunoglobulin G 15.1 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 6.38 mmol/L.
- Day 1,629 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 5.83 mmol/L.

Other clinical attributes
- Day 1: Weight: 55 kg; Height: 162 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1219_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 278 days.
- Sample MMRF_1219_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 278 days.
